Gene-level copy-number profile of tumor specimen ALCH-B2RX-TTP1-A from ALCHEMIST case ALCH-B2RX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.9 years (25,167 days).
Specimen ALCH-B2RX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ddf714f8-7ce6-4c67-99ea-7c8943b3a9ab.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2RX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/7e72fc6b-a7f9-4907-8ca3-02603429248f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 209; copy number 1: 57; copy number 2: 10,903; copy number 3: 512; copy number 4: 37,971; copy number 5: 2,445; copy number 6: 6,673; copy number 7: 6; copy number 8: 93; copy number 9: 1; copy number 10: 14; copy number 11: 7; copy number 13: 5; copy number 23: 2.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:22,056,709–22,057,638, 1 gene (within-gene range 0–11): OR4H6P.
- chr21:7,744,962–8,603,984, 27 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 29 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,632,568–2,636,620, 1 gene, copy number 9 (within-gene range 3–9): MMEL1-AS1.
- chr14:18,333,726–18,419,273, 4 genes, copy number 13: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:104,815,449–104,815,753, 1 gene, copy number 10: AL590326.1.
- chr15:21,951,242–21,951,323, 1 gene, copy number 13: MIR5701-3.
- chr15:21,990,074–22,095,857, 5 genes, copy number 11 (within-gene range 0–30): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P.
- chr15:22,070,241–22,095,472, 2 genes, copy number 11 (within-gene range 11–30): OR4M2, OR4N4.
- chr16:16,290,135–16,368,942, 12 genes, copy number 10: AC136624.2, MIR3179-2, MIR3670-2, AC138969.2, MIR3180-2, PKD1P1, Y_RNA, AC138969.1, MIR6511A2, MIR6770-2, AC138969.3, MIR6511A3.
- chr19:1,852,382–1,863,579, 3 genes, copy number 10–23: AC012615.3, KLF16, AC012615.4.

Autosomal genes at a single copy (total copy number 1): 42. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
